Somatic mutation profile of tumor specimen 0DQB2T from CCDI case PBCBRZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 12.9 years (4,707 days).
Specimen 0DQB2T: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 657ff0d0-fa70-437a-bfad-9aa6e88284a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQB20 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b436bd3-bb68-4dc6-96b0-3f6782c75594

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Missense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR4A5 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 33/821 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.094); catalogued as rs762367006; called by muse, mutect2
- GABRA2 | c.33G>A p.Q11= | Silent (SNP) | VAF 255/787 reads (32%) | called by muse, mutect2, varscan2
- SKI | c.1731C>T p.L577= | Silent (SNP) | VAF 233/742 reads (31%) | catalogued as rs1030112708; called by muse, mutect2, varscan2
- STARD3 | c.1139+81G>T | Intron (SNP) | VAF 8/87 reads (9%) | called by muse, mutect2, varscan2
